Somatic mutation profile of tumor specimen TCGA-R6-A6KZ-01A (aliquot TCGA-R6-A6KZ-01A-11D-A31U-09) from TCGA case TCGA-R6-A6KZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 42.5 years (15,512 days).
Specimen TCGA-R6-A6KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dff734d4-40d6-4f45-baae-30d40620c012.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-R6-A6KZ-10A (Blood Derived Normal), aliquot TCGA-R6-A6KZ-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b1437cb-a40b-4f96-955f-a2a2c0c3dc3f

The open-access MAF lists 166 somatic variants for this specimen: 123 protein-altering or splice-affecting, 40 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 40, Nonsense Mutation 3, Splice Site 2, Intron 2, Splice Region 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1638G>C p.Q546H | Missense Mutation (SNP) | VAF 9/81 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55883555, COSV55928679, COSV55957396; called by muse, mutect2, varscan2
- SMAD4 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 30/56 reads (54%) | hotspot (GDC flag); catalogued as rs377767360, CM000742, COSV61685033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 25/47 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTPA | c.661C>T p.R221W | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs35916840, CM981967; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRA2 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs148143932; called by muse, mutect2, varscan2
- ADGRB1 | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); catalogued as rs748528325; called by muse, mutect2, varscan2
- ADRA1A | c.505G>T p.A169S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.3); catalogued as COSV52369416; called by muse, mutect2
- CD163L1 | c.2902C>T p.H968Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV58024433; called by muse, mutect2, varscan2
- CD1E | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63772776; called by muse, mutect2, varscan2
- CNTN3 | c.1872C>A p.N624K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV55183789; called by muse, mutect2
- COL11A1 | c.5344G>T p.D1782Y | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62190669; called by muse, mutect2, varscan2
- CPXCR1 | c.794T>G p.V265G | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV52163256; called by muse, mutect2, varscan2
- DIAPH2 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61292226; called by muse, mutect2, varscan2
- DNAH3 | c.9199G>A p.D3067N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1389747763, COSV99767668; called by muse, mutect2, varscan2
- DRD1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101192376, COSV67104835; called by muse, mutect2, varscan2
- ERBB2 | c.2350C>T p.R784C | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs968832437, COSV54065970, COSV54078294; called by muse, mutect2, varscan2
- EVX2 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs768525510; called by muse, mutect2, varscan2
- FBXO27 | c.832G>A p.V278M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as rs746754083; called by muse, mutect2, varscan2
- FGR | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV64969598; called by muse, mutect2, varscan2
- GJB5 | c.160A>G p.N54D | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as rs750367033; called by muse, mutect2, varscan2
- H1-5 | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV58900773; called by muse, mutect2, varscan2
- HMCN1 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54876273, COSV54893537; called by muse, mutect2, varscan2
- HOXB3 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs774250247, COSV57487585; called by muse, mutect2, varscan2
- HVCN1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs948351485, COSV99657165; called by muse, mutect2, varscan2
- KCNN2 | c.214G>A p.E72K (on ENST00000264773; = p.E284K on NM_021614.4) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.385); catalogued as rs1451149026, COSV53282678, COSV53288831; called by mutect2, varscan2
- KCNQ3 | c.1047C>A p.G349= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as COSV66467407; called by muse, mutect2, varscan2
- KDM6B | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs769034818; called by muse, mutect2, varscan2
- LCN9 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs374188235; called by muse, mutect2, varscan2
- LRP2 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs368619363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAG | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs201311667; called by muse, mutect2, varscan2
- MAOA | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs780647851, COSV58644363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP4K2 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1301946500; called by muse, mutect2, varscan2
- MCOLN1 | c.689A>G p.N230S | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs774998740; called by muse, mutect2, varscan2
- MYH4 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs763267052, COSV55111968; called by muse, mutect2, varscan2
- MYH4 | c.2999A>C p.K1000T | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs1426812861, COSV55115994, COSV55127068; called by muse, mutect2, varscan2
- NEB | c.16119A>C p.E5373D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs774812050; called by muse, varscan2
- NOMO3 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs531823444; called by mutect2, varscan2
- OR2T33 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 82/196 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs139302289, COSV100532243; called by muse, mutect2, varscan2
- OR4C6 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100051758, COSV58603674, COSV58606703; called by muse, mutect2, varscan2
- OXA1L | c.1337G>A p.R446Q (on ENST00000285848; = p.R386Q on NM_005015.5) | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs940703036, COSV99590991; called by muse, mutect2
- PASD1 | c.1433A>C p.N478T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV64855731; called by muse, mutect2, varscan2
- PCDH19 | c.3026G>T p.G1009V (on ENST00000373034 / NM_001184880.2; = p.G961V on NM_020766.3) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV55264362; called by muse, mutect2, varscan2
- PDZD2 | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99225858; called by muse, mutect2, varscan2
- PKHD1L1 | c.6567A>C p.K2189N | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as COSV65748711; called by muse, mutect2, varscan2
- PLAU | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs371297216; called by muse, mutect2, varscan2
- SALL2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs753189477, COSV58104956; called by muse, mutect2
- SELL | c.350A>C p.N117T (on ENST00000650983; = p.N104T on NM_000655.5) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV52550098; called by muse, mutect2, varscan2
- SI | c.4643T>G p.L1548R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52268049; called by muse, mutect2, varscan2
- SKOR1 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs757856127, COSV100408265; called by muse, mutect2
- SLAMF8 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); catalogued as COSV56989742; called by muse, mutect2, varscan2
- SORCS3 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63794687; called by muse, mutect2, varscan2
- SPTA1 | c.4693C>G p.L1565V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63757353; called by muse, mutect2, varscan2
- SPTAN1 | c.1464G>A p.A488= | Splice Region (SNP) | VAF 20/62 reads (32%) | catalogued as rs749835470; called by muse, mutect2, varscan2
- TBX22 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1431655517; called by muse, mutect2, varscan2
- TTC39A | c.1493A>C p.E498A (on ENST00000447632 / NM_001297665.1; = p.E463A on NM_001080494.3) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV52958345; called by muse, mutect2, varscan2
- UQCRFS1 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs766671534, COSV59185294; called by muse, mutect2, varscan2
- USP38 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1393709707; called by muse, mutect2, varscan2
- ZC3H7A | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.081); catalogued as rs368731907; called by muse, mutect2, varscan2
- ZIC1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99291723; called by muse, mutect2, varscan2
- ZNF208 | c.2642A>T p.K881I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs572727442; called by muse, mutect2, varscan2
- ZNF354A | c.636A>C p.K212N | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100234386; called by muse, mutect2, varscan2
- ZNF491 | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 28/48 reads (58%) | catalogued as rs139779307; called by muse, mutect2, varscan2
- ZNF600 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375256564; called by muse, mutect2, varscan2
- ZNF763 | c.280T>G p.F94V (on ENST00000358987 / NM_001367172.2; = p.F97V on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.954); catalogued as COSV100676253; called by muse, mutect2, varscan2
- ZNF93 | c.1751A>C p.K584T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as COSV59376853; called by muse, mutect2, varscan2
- ABCA1 | c.4937T>A p.V1646E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ACTR8 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3476C>T p.S1159F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- AKT1S1 | c.500G>A p.C167Y (on ENST00000344175 / NM_001098633.4; = p.C187Y on NM_032375.5) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK2 | c.9243C>A p.D3081E | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARID1B | c.4387C>T p.Q1463* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- ATP1B4 | c.571G>T p.D191Y (on ENST00000218008 / NM_001142447.3; = p.D187Y on NM_012069.5) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRNL1 | c.3895C>G p.P1299A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BBS5 | c.1015G>C p.V339L | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- CCDC80 | c.2146C>A p.L716I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- CCNA1 | c.601C>A p.L201I | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCR9 | c.994C>A p.L332M (on ENST00000357632 / NM_031200.3; = p.L320M on NM_006641.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CHL1 | c.692A>C p.K231T (on ENST00000397491 / NM_001253387.1; = p.K247T on NM_006614.4) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- COL3A1 | c.2081T>C p.L694P | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CPLANE1 | c.8614G>A p.A2872T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- DNAH11 | c.3464C>A p.S1155Y | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSP | c.5575C>A p.Q1859K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2
- FAM120A | c.3188A>G p.Q1063R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- GABRP | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALE | c.481_486del p.K161_F162del | In Frame Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- GNB4 | c.171A>C p.K57N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR19 | c.924T>G p.S308R | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- GRIA1 | c.182T>C p.I61T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- H1-2 | c.350A>G p.K117R | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- HCN1 | c.1208C>T p.S403L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- HTR3D | c.998T>C p.V333A (on ENST00000382489 / NM_001163646.2; = p.V158A on NM_182537.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ITGA2 | c.3448G>T p.V1150F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- KIF4B | c.2981T>G p.L994R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- LBX1 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LENG9 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAML2 | c.3098G>A p.S1033N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED1 | c.1159A>C p.S387R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MED13 | c.2090C>A p.P697Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MPDZ | c.55A>C p.T19P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSH5 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH2 | c.4663-2A>C p.X1555_splice | Splice Site (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- NSUN3 | c.549G>C p.L183F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- OPTC | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- OR5R1 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- OR8B2 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2
- PRKCB | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- PRKD2 | c.2203T>A p.W735R | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTX3 | c.611T>G p.L204R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, varscan2
- SCN5A | c.769A>C p.T257P | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETX | c.1326A>C p.E442D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLIT3 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC2 | c.2163G>A p.M721I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SMG8 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SP3 | c.384G>C p.Q128H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPECC1L | c.1768G>A p.V590M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAP1 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SYNE1 | c.12956G>C p.S4319T (on ENST00000367255 / NM_182961.4; = p.S4248T on NM_033071.3) | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TM4SF20 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.168); called by muse, mutect2
- TTN | c.11608A>G p.S3870G (on ENST00000591111; = p.S3824G on NM_003319.4) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- ZFP28 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ZNF677 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZSWIM3 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- ATP10A | c.2118G>A p.A706= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs769429272; called by muse, mutect2, varscan2
- BRINP3 | c.1410C>T p.S470= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV66514388, COSV66515243; called by muse, mutect2, varscan2
- CACNA1C | c.168C>T p.I56= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs763760402, COSV59708272; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD1B | c.831G>T p.L277= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs781566909; called by muse, mutect2, varscan2
- COL11A1 | c.3849A>G p.E1283= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- CSMD3 | c.6940A>C p.R2314= (on ENST00000297405 / NM_001363185.1; = p.R2210= on NM_052900.3) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52160571, COSV99846677; called by muse, mutect2, varscan2
- CTNND2 | c.339C>A p.I113= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs374819899, COSV58864314; called by muse, mutect2, varscan2
- EPHA6 | c.1683T>C p.A561= | Silent (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- EVC2 | c.1110C>T p.S370= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs748718225; called by muse, mutect2, varscan2
- FEN1 | c.568C>T p.L190= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs753589075; called by muse, mutect2, varscan2
- GBP2 | c.1689C>T p.F563= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs375772970; called by muse, mutect2, varscan2
- GUCY2F | c.2403T>G p.T801= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as COSV54298824; called by muse, mutect2, varscan2
- IGF1R | c.723G>A p.A241= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs370559574; called by mutect2, varscan2
- KIR3DL3 | c.996C>T p.I332= | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, mutect2, varscan2
- KLB | c.136C>T p.L46= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- L2HGDH | c.1078C>T p.L360= | Silent (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- LY9 | c.780C>T p.V260= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs375232078; called by muse, varscan2
- MAST4 | c.621G>A p.A207= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs1277714381, COSV101282560; called by muse, mutect2, varscan2
- MOB3C | c.345G>A p.P115= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs893771080; called by muse, mutect2, varscan2
- MT1F | c.135C>T p.A45= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- NPAP1 | c.2202A>G p.Q734= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs765337506; called by muse, mutect2, varscan2
- NYX | c.54G>T p.L18= | Silent (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- OR10A5 | c.498T>C p.S166= | Silent (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- PLB1 | c.1572C>T p.H524= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- PRB4 | c.471T>C p.P157= | Silent (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- PYCR3 | c.708C>T p.T236= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- SAMD9 | c.862A>C p.R288= | Silent (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- SOGA1 | c.3261G>A p.L1087= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1163771839; called by muse, mutect2, varscan2
- SVEP1 | c.9378G>A p.P3126= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs760674753, COSV52839020; called by muse, mutect2, varscan2
- TDRKH | c.942T>C p.A314= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs773081754; called by muse, mutect2, varscan2
- TGFB1I1 | c.150A>G p.S50= (on ENST00000394863 / NM_001042454.3; = p.S33= on NM_015927.4) | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- THAP12 | c.546T>C p.P182= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- TLE4 | c.432C>T p.L144= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1045603633; called by muse, mutect2
- TMEM8B | c.792C>T p.V264= | Silent (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.3417G>A p.V1139= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- TRPC6 | c.852T>C p.A284= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs778214024; called by muse, mutect2, varscan2
- TUBGCP3 | c.2649C>T p.N883= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs758513847; called by muse, mutect2, varscan2
- TUBGCP4 | c.900G>A p.L300= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- ZCCHC12 | c.201A>G p.Q67= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- ZNF347 | c.1452T>G p.P484= | Silent (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- FOXP1 | c.180+244T>G | Intron (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- RPL26P30 | n.697G>A | RNA (SNP) | VAF 19/77 reads (25%) | catalogued as rs556019721; called by muse, mutect2, varscan2
- TPH2 | c.609-10872G>A | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as rs765117576, COSV61592172; called by muse, mutect2, varscan2
